Somatic mutation profile of tumor specimen MP2PRT-PAPLBX-TMP1-A (aliquot MP2PRT-PAPLBX-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPLBX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (965 days).
Specimen MP2PRT-PAPLBX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 060dec59-6610-4f98-9cbb-f24cfa76888d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPLBX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPLBX-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12628145-b4ce-4b18-bbb1-f18e19e627f8

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770551610, CM166266, CM166267, COSV58781145; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/280 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CRTAC1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1301110074, COSV100086171; called by muse, mutect2, varscan2
- PCDHA13 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); catalogued as COSV56521480, COSV56527393; called by muse, mutect2
- PFAS | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 81/322 reads (25%) | catalogued as rs778134430, COSV58980066; called by muse, mutect2, varscan2
- TJP1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 28/447 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs778030292, COSV62044242; called by muse, mutect2
- ZNF728 | c.1589A>G p.H530R | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1395020667; called by muse, mutect2
- ERMAP | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.073); called by muse, mutect2
- RBM10 | c.1704C>T p.D568= | Silent (SNP) | VAF 120/298 reads (40%) | catalogued as rs781845707; called by muse, mutect2, varscan2
- SOHLH1 | c.939G>A p.S313= | Silent (SNP) | VAF 104/288 reads (36%) | catalogued as rs1399606342; called by muse, mutect2, varscan2
- STARD13 | c.170-18367G>T | Intron (SNP) | VAF 78/221 reads (35%) | called by muse, mutect2, varscan2
